Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3454, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3454-01A (Primary Tumor).

[page 1 of 2]
Clinical History/Diagnosis: Right Kidney and Ureteral CA

Source of Specimen(s):

- 1: right kidney and ureter
- 2: right distal ureter
- 3: Stent

Gross Description:

Received in three parts.

Source of Tissue: 1. Labeled # 1, "right kidney and ureter"

Gross Description: Received fresh in a container labeled , right kidney and ureter". It consists of a right radical nephrectomy and attached ureter weighing 492-grams and consists of a segment of right ureter measuring 27.0 cm in length x 0.9 cm and right kidney measuring 10.0 x 6.0 x 5.5 cm. The fat overlying the ureter is markedly firm and full. Sections show a patent lumen and slightly thickened wall however, no gross tumor is identified. The vascular margins are unremarkable. The kidney is bivalved disclosing a markedly distended calyceal system and renal pelvis. In the inferior pole there is a bulging circumscribed mass measuring 4.3 x 4.0 cm. The mass has a red to orange cut surface and pushes on the small amount of the remaining parenchyma and overlying capsule, however, no invasion is found into the capsule. The lesion is 4.5 cm from the hilum. Representative sections are submitted in 1A-O.

Designation of Sections: 1A- vascular and ureter margins, 1B-1J- multiple representative sections of the ureter from distal to proximal, 1K- right kidney tumor, 1L- right kidney tumor in relationship to capsule, 1M- right kidney tumor in relationship to adjacent parenchyma, 1N- additional inked fat overlying right kidney mass, 1O- renal pelvis

Source of Tissue: 2. Labeled # 2, "right distal ureter"

Frozen Section Diagnosis: 2FS- NO TUMOR SEEN PER

Gross Description: Received fresh from O.R. for frozen section consultation in a container labeled ", right distal ureter". It consists of a tan to red segment of ureter measuring 0.5 x 0.8 x 0.8 cm with some attached associated fibroadipose and fibrous tissue measuring up to 0.8 cm from point of attachment. All of the tissue was submitted for frozen section and the residue is in 2FS.

Source of Tissue: 3. Labeled # 3, "stent"

[page 2 of 2]
Gross Description: Received fresh in a container labeled "stent". It consists of a segment of blue rubber tubing measuring 37.0 cm in length x 0.3 cm in diameter. There is some dried blood associated with the specimen and at one end there is stitch. The specimen is otherwise in good repair. No blood or tissue submitted, gross only.

Final Diagnosis:

1. Right kidney and ureter, radical nephrectomy:

- Renal cell carcinoma, clear cell (conventional) type, [REDACTED]s nuclear grade III / IV, 4.3 cm grossly, with focal necrosis, confined to the kidney and is less than 1 mm to the closest inked circumferential margin.
- Angiolymphatic invasion is not identified.
- Ureter with focal moderate dysplasia, and acute and chronic inflammation which is mostly in the surrounding fibroadipose tissue.
- Renal pelvis with no tumor seen.
- Vascular and ureteral margins with no tumor seen.
- Non-neoplastic kidney with atrophy.

2. Right distal ureter:

- Focally denuded urothelium; No tumor seen.

3. Gross Diagnosis Only (stent).

- pT1b Nx Mx

Procedures/Addenda

FC Cytogenetics Solid Tumor

Results-Comments

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Right Renal Cancer

KARYOTYPE: Specimen inadequate for cytogenetic analysis.

RESULTS: The renal sample was harvested after ten days in culture. The cells failed to grow, and no metaphases were found in a scan of ten slides.

Source: NCI Genomic Data Commons file c964fa7c-1754-4503-9532-6d9de4461eb3 (TCGA-AK-3454.E0E1C66D-F679-4DC5-936C-9DC752B5BEBE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).